Somatic mutation profile of tumor specimen C3L-06427-03 (aliquot CPT0373310006) from CPTAC case C3L-06427, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 79.5 years (29,032 days).
Specimen C3L-06427-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Foot; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e0f58d7-dba7-4f72-ae02-3115a55a1bb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06427-31 (Blood Derived Normal), aliquot CPT0374550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a3db1d5-7e08-4434-ba43-6e20e2038dc7

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Intron 2, Frame Shift Ins 2, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 140/289 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BCL9 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 502/759 reads (66%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs781871288; called by muse, mutect2, varscan2
- COL9A1 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs756647529; called by muse, mutect2
- CRYGB | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 124/401 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs370450145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH8 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 135/355 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs777367404, COSV59194801; called by muse, mutect2, varscan2
- INTS6L | c.2576C>T p.S859L | Missense Mutation (SNP) | VAF 43/286 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100878053; called by muse, mutect2, varscan2
- KRT17 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs564768263, COSV100245236; called by muse, mutect2, varscan2
- KRTAP5-2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 208/553 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV101295067, COSV69014941; called by muse, mutect2, varscan2
- OR2M4 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 424/588 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs761848850, COSV60707174; called by muse, mutect2, varscan2
- PPP1R15A | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 134/505 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); catalogued as rs750620616; called by muse, mutect2, varscan2
- SEL1L3 | c.2993C>T p.T998M | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.179); catalogued as rs368070857; called by muse, mutect2, varscan2
- TIAM2 | c.2896G>C p.V966L | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.117); catalogued as COSV59690637; called by muse, mutect2, varscan2
- TINAG | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs755363828; called by muse, mutect2, varscan2
- TRANK1 | c.7334G>T p.W2445L | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57163200; called by muse, mutect2, varscan2
- ACSM2B | c.1369C>A p.Q457K | Missense Mutation (SNP) | VAF 109/422 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.043); called by mutect2, varscan2
- ARFIP2 | c.722dup p.D241Efs*19 | Frame Shift Ins (INS) | VAF 102/374 reads (27%) | called by mutect2, pindel, varscan2
- BCR | c.2920A>G p.I974V | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- C19orf73 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 170/541 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CD34 | c.837T>G p.D279E | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.422); called by muse, mutect2
- CFAP52 | c.1124T>A p.M375K | Missense Mutation (SNP) | VAF 84/449 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DZIP3 | c.3122T>G p.L1041R | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR5B | c.2134T>C p.S712P | Missense Mutation (SNP) | VAF 206/463 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KIAA1614 | c.1692G>T p.Q564H | Missense Mutation (SNP) | VAF 93/708 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KLHL40 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 12/386 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- MARVELD3 | c.327A>C p.K109N | Missense Mutation (SNP) | VAF 16/511 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- METTL14 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); called by muse, mutect2
- NPHP3 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 90/342 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OR51A7 | c.193A>C p.M65L | Missense Mutation (SNP) | VAF 83/446 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PIEZO2 | c.4054T>G p.Y1352D | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PKHD1L1 | c.8380A>T p.M2794L | Missense Mutation (SNP) | VAF 22/423 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- PLCB1 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 57/434 reads (13%) | called by muse, mutect2, varscan2
- SAMD9 | c.2606T>G p.L869W | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- SEC14L3 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SQSTM1 | c.151_154dup p.A52Gfs*20 | Frame Shift Ins (INS) | VAF 65/457 reads (14%) | called by mutect2, pindel, varscan2
- TRPM7 | c.544A>G p.K182E | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- USP36 | c.499_501dup p.L167dup | In Frame Ins (INS) | VAF 152/330 reads (46%) | called by mutect2, pindel, varscan2
- UVRAG | c.371T>A p.I124N | Missense Mutation (SNP) | VAF 137/383 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VMA21 | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- VPS13A | c.4645T>C p.S1549P | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP1 | c.1612A>C p.T538P | Missense Mutation (SNP) | VAF 23/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZBTB12 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 38/954 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- A2ML1 | c.1485G>A p.G495= | Silent (SNP) | VAF 96/281 reads (34%) | called by muse, mutect2, varscan2
- AC005833.1 | c.1668C>T p.H556= | Silent (SNP) | VAF 71/350 reads (20%) | called by muse, mutect2, varscan2
- ANKS1A | c.312G>A p.A104= | Silent (SNP) | VAF 65/375 reads (17%) | catalogued as rs1311766028; called by muse, mutect2, varscan2
- ARHGEF9 | c.228C>A p.P76= | Silent (SNP) | VAF 101/478 reads (21%) | catalogued as COSV53638596, COSV53640200; called by muse, mutect2, varscan2
- C6orf15 | c.126C>T p.T42= | Silent (SNP) | VAF 237/692 reads (34%) | catalogued as rs1447281152; called by muse, mutect2, varscan2
- DOP1A | c.1521C>T p.P507= | Silent (SNP) | VAF 12/432 reads (3%) | called by muse, mutect2
- FER1L5 | c.4668C>T p.N1556= (on ENST00000623019; = p.N1529= on NM_001293083.2) | Silent (SNP) | VAF 99/412 reads (24%) | called by muse, mutect2, varscan2
- GRM4 | c.1848C>A p.P616= | Silent (SNP) | VAF 80/527 reads (15%) | called by muse, mutect2, varscan2
- HEATR5B | c.2133T>C p.T711= | Silent (SNP) | VAF 206/465 reads (44%) | called by muse, mutect2, varscan2
- HHIPL2 | c.1971C>T p.A657= | Silent (SNP) | VAF 12/382 reads (3%) | catalogued as rs1400523053; called by muse, mutect2
- LAMA5 | c.1128G>T p.R376= | Silent (SNP) | VAF 54/369 reads (15%) | catalogued as rs770353037; called by muse, mutect2, varscan2
- LIN28A | c.528G>A p.L176= | Silent (SNP) | VAF 18/464 reads (4%) | called by muse, mutect2
- PAK5 | c.585T>C p.F195= | Silent (SNP) | VAF 149/496 reads (30%) | called by muse, mutect2, varscan2
- SGSM3 | c.1407G>A p.R469= | Silent (SNP) | VAF 81/410 reads (20%) | called by muse, mutect2, varscan2
- SLC40A1 | c.1233G>A p.R411= | Silent (SNP) | VAF 148/444 reads (33%) | called by muse, mutect2, varscan2
- TOMM40L | c.309C>T p.S103= | Silent (SNP) | VAF 19/678 reads (3%) | catalogued as rs1358086519; called by muse, mutect2
- ZNF629 | c.1257C>T p.N419= | Silent (SNP) | VAF 207/539 reads (38%) | called by muse, mutect2, varscan2
- DNAH5 | c.2259+1584C>T | Intron (SNP) | VAF 39/222 reads (18%) | called by muse, mutect2, varscan2
- PPP4R4 | c.295-3275C>T | Intron (SNP) | VAF 118/381 reads (31%) | called by muse, mutect2, varscan2
